Somatic mutation profile of tumor specimen TCGA-S5-AA26-01A (aliquot TCGA-S5-AA26-01A-11D-A38G-08) from TCGA case TCGA-S5-AA26, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 46.5 years (16,972 days).
Specimen TCGA-S5-AA26-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0e5423a-f140-40f6-b958-23cecee964cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S5-AA26-10A (Blood Derived Normal), aliquot TCGA-S5-AA26-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/beb6dc07-c319-40f9-a923-ed0e6761b2c0

The open-access MAF lists 252 somatic variants for this specimen: 193 protein-altering or splice-affecting, 54 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 176, Silent 54, Nonsense Mutation 13, Intron 2, Frame Shift Ins 1, Splice Site 1, 5'Flank 1, Splice Region 1, 3'UTR 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG1 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.177); catalogued as COSV59211193; called by muse, mutect2, varscan2
- ACAN | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.155); catalogued as rs1482228246, COSV61370792; called by muse, mutect2, varscan2
- ACAN | c.6508G>C p.E2170Q | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs777387397, COSV61370814, COSV61371250; called by muse, varscan2
- AFF4 | c.3466C>T p.R1156C | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs112871745, COSV54796199; called by muse, mutect2, varscan2
- AHR | c.1149G>C p.Q383H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as COSV54121404, COSV54127162; called by muse, mutect2, varscan2
- AK4 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs776921061, COSV59199769; called by muse, mutect2, varscan2
- AP4B1 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs149723440; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF10 | c.2563G>A p.E855K (on ENST00000398564; = p.E830K on NM_014629.4) | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.175); catalogued as rs544009495, COSV50684933; called by muse, mutect2, varscan2
- ASH1L | c.5081C>T p.S1694L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as rs1303542858, COSV100853230, COSV64214692; called by muse, mutect2, varscan2
- ASPHD1 | c.861C>G p.F287L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.721); catalogued as COSV100435489, COSV58105023; called by muse, mutect2, varscan2
- ASXL2 | c.974C>G p.S325* | Nonsense Mutation (SNP) | VAF 4/61 reads (7%) | catalogued as COSV55453179, COSV99710695; called by muse, mutect2
- ATM | c.3637C>A p.H1213N | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV53779808; called by muse, mutect2, varscan2
- ATM | c.7702A>G p.R2568G | Missense Mutation (SNP) | VAF 56/97 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV53779828; called by muse, mutect2, varscan2
- ATP8A2 | c.2233C>T p.Q745* | Nonsense Mutation (SNP) | VAF 36/69 reads (52%) | catalogued as COSV99681080; called by muse, mutect2, varscan2
- BRI3BP | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58297415; called by muse, mutect2, varscan2
- BSN | c.11575C>G p.Q3859E | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.056); catalogued as COSV56529398; called by muse, mutect2
- C3 | c.4361C>G p.S1454C | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV55569768; called by muse, mutect2, varscan2
- CACNB2 | c.1564G>A p.V522M (on ENST00000324631 / NM_201596.3; = p.V467M on NM_000724.4) | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1278302013, COSV56650455; called by muse, mutect2, varscan2
- CALB1 | c.69C>G p.F23L | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV55369966; called by muse, mutect2, varscan2
- CCDC149 | c.258G>C p.R86S | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV60882609; called by muse, mutect2, varscan2
- CCDC30 | c.916C>T p.R306* (on ENST00000340612; = p.R263* on NM_001080850.3) | Nonsense Mutation (SNP) | VAF 40/79 reads (51%) | catalogued as rs780702656, COSV59604704; called by muse, mutect2, varscan2
- CCDC88A | c.4631C>T p.S1544F (on ENST00000436346 / NM_001365480.1; = p.S1516F on NM_018084.5) | Missense Mutation (SNP) | VAF 71/84 reads (85%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs756477275, COSV55071081; called by muse, mutect2, varscan2
- CD93 | c.446C>G p.S149C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1157154077, COSV55667640, COSV55669352; called by muse, mutect2, varscan2
- CDC42BPB | c.4019C>G p.S1340C | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.778); catalogued as COSV63477214; called by muse, mutect2, varscan2
- CEACAM3 | c.259C>G p.Q87E | Missense Mutation (SNP) | VAF 203/309 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.314); catalogued as COSV55763484; called by muse, mutect2, varscan2
- CFAP94 | c.2105C>G p.S702C (on ENST00000320267 / NM_001352064.2; = p.S708C on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.155); catalogued as rs1565603104, COSV57237345; called by muse, mutect2, varscan2
- CHD9 | c.6058C>G p.Q2020E | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.104); catalogued as COSV54617502; called by muse, mutect2, varscan2
- CHERP | c.1902C>G p.I634M | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1353324989, COSV52223905, COSV52228109; called by muse, mutect2, varscan2
- CNTN4 | c.1648G>C p.E550Q | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as rs1471980479, COSV61881272, COSV61882180; called by muse, mutect2, varscan2
- CNTNAP2 | c.144C>A p.F48L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV100673731, COSV62267733; called by muse, mutect2, varscan2
- COL5A3 | c.3527C>A p.P1176H | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1283978086, COSV53405271, COSV53420560; called by muse, mutect2, varscan2
- COL7A1 | c.1745G>T p.R582L | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.154); catalogued as COSV60404192; called by muse, mutect2, varscan2
- CORO6 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1447995407, COSV61471502; called by muse, mutect2, varscan2
- CPT1C | c.1802C>T p.T601M | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747214352, COSV54923060; called by muse, mutect2, varscan2
- CREM | c.337G>C p.E113Q (on ENST00000429130; = p.E64Q on NM_001881.3) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59766082, COSV59770484; called by muse, mutect2, varscan2
- CRTC2 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.16); PolyPhen benign (0.343); catalogued as COSV57846078; called by muse, mutect2, varscan2
- CSMD1 | c.3780G>C p.L1260F (on ENST00000520002; = p.L1259F on NM_033225.6) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV59394452; called by muse, mutect2, varscan2
- CSMD3 | c.8398C>A p.L2800I (on ENST00000297405 / NM_001363185.1; = p.L2631I on NM_052900.3) | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1426892375, COSV52341280; called by muse, mutect2, varscan2
- CTNNBL1 | c.1374G>C p.K458N | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1299614233, COSV63747686; called by muse, mutect2, varscan2
- CYP39A1 | c.598G>C p.D200H | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV51499826; called by muse, mutect2, varscan2
- DAB2 | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV57919581; called by muse, mutect2, varscan2
- DDX21 | c.2030G>A p.G677E | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV62557076; called by muse, mutect2, varscan2
- DHRS3 | c.376G>C p.V126L | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66108564, COSV66108976; called by muse, mutect2, varscan2
- DIP2C | c.2503C>A p.L835M | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.593); catalogued as COSV55182059; called by muse, mutect2, varscan2
- DOCK6 | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.227); catalogued as rs750382885, COSV52948765; called by muse, mutect2, varscan2
- DOP1A | c.205C>A p.Q69K | Missense Mutation (SNP) | VAF 100/221 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52719470; called by muse, mutect2, varscan2
- DOP1B | c.164C>G p.S55C | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV54281968; called by muse, mutect2, varscan2
- EGF | c.2551G>C p.E851Q | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as COSV54485702; called by muse, mutect2
- ENAM | c.2769C>G p.I923M | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs1293482859, COSV68537247; called by muse, mutect2, varscan2
- EP400 | c.2239C>T p.Q747* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as COSV100200843; called by muse, mutect2, varscan2
- EPS8L1 | c.838G>C p.E280Q (on ENST00000201647 / NM_133180.3; = p.E153Q on NM_017729.3) | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.88); catalogued as COSV52387065; called by muse, mutect2, varscan2
- EXO1 | c.2069C>G p.S690* | Nonsense Mutation (SNP) | VAF 41/62 reads (66%) | catalogued as COSV100799685; called by muse, mutect2, varscan2
- FANCA | c.3928G>A p.E1310K | Missense Mutation (SNP) | VAF 82/192 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.229); catalogued as COSV57070985, COSV57073895; called by muse, mutect2, varscan2
- FBN2 | c.6529G>C p.E2177Q | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.673); catalogued as COSV52548733; called by muse, mutect2, varscan2
- FBN3 | c.1733C>T p.T578M | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as rs765508615, COSV54474910; called by muse, mutect2, varscan2
- FBN3 | c.823C>G p.P275A | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV54474920; called by muse, mutect2, varscan2
- FFAR3 | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as COSV100588154; called by muse, mutect2
- FGF12 | c.680C>G p.S227C (on ENST00000454309 / NM_021032.5; = p.S165C on NM_004113.6) | Missense Mutation (SNP) | VAF 91/186 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV53191852; called by muse, mutect2, varscan2
- FGF19 | c.305G>C p.C102S | Missense Mutation (SNP) | VAF 23/598 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99594295; called by muse, mutect2
- FGFBP2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs746140893, COSV52588685; called by muse, mutect2, varscan2
- FOXJ2 | c.631G>T p.V211L | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.079); catalogued as COSV50825880; called by muse, mutect2, varscan2
- FUT5 | c.788C>G p.S263C | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53139173; called by muse, mutect2, varscan2
- GAN | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs760587601, COSV73721491; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GGA3 | c.524C>G p.S175C (on ENST00000537686 / NM_138619.4; = p.S142C on NM_014001.5) | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55459392; called by muse, mutect2, varscan2
- GLUD1 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 53/255 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53281654; called by muse, mutect2, varscan2
- GOLGA4 | c.6277G>A p.E2093K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as rs1405321571, COSV100728771; called by muse, mutect2, varscan2
- GREB1 | c.1198G>T p.D400Y | Missense Mutation (SNP) | VAF 62/64 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52191890; called by muse, mutect2, varscan2
- GRIN2C | c.2129C>T p.S710L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs373406017, COSV53118624; called by muse, mutect2, varscan2
- GTF2H4 | c.1090-1G>C p.X364_splice | Splice Site (SNP) | VAF 51/93 reads (55%) | catalogued as COSV52561526; called by muse, mutect2, varscan2
- HDAC11 | c.844G>C p.D282H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55474747; called by muse, mutect2, varscan2
- HEATR1 | c.2278G>C p.D760H | Missense Mutation (SNP) | VAF 200/210 reads (95%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as COSV63982525; called by muse, mutect2, varscan2
- IHO1 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99605971; called by muse, mutect2
- INPP5F | c.3179C>T p.S1060L | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as rs1246728148, COSV62824301; called by muse, mutect2, varscan2
- IQGAP2 | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as COSV57184408; called by muse, mutect2, varscan2
- IRX5 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV58060142; called by muse, mutect2, varscan2
- JAK1 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 41/45 reads (91%) | catalogued as COSV61087251; called by muse, mutect2, varscan2
- KCNJ13 | c.934C>G p.Q312E | Missense Mutation (SNP) | VAF 100/112 reads (89%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV52086217; called by muse, mutect2, varscan2
- KCNJ9 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63632556; called by muse, mutect2, varscan2
- KIF26B | c.1176G>T p.Q392H | Missense Mutation (SNP) | VAF 101/165 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as COSV63653844; called by muse, mutect2, varscan2
- KLF6 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 103/214 reads (48%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.666); catalogued as COSV51496449; called by muse, mutect2, varscan2
- KLHDC8B | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV60412959; called by muse, mutect2, varscan2
- KLHL25 | c.1498G>C p.D500H | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.222); catalogued as COSV61996725; called by muse, mutect2, varscan2
- KMT2D | c.2870T>A p.L957* | Nonsense Mutation (SNP) | VAF 13/25 reads (52%) | catalogued as COSV99979290; called by muse, mutect2, varscan2
- KRT80 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV57547768; called by muse, mutect2, varscan2
- LCA5L | c.1943C>G p.S648C | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55747719; called by muse, mutect2, varscan2
- LGI1 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.727); catalogued as COSV65058909, COSV65059525; called by muse, mutect2, varscan2
- LPIN1 | c.2317G>C p.E773Q | Missense Mutation (SNP) | VAF 84/92 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV56771860; called by muse, mutect2, varscan2
- LTBP4 | c.2641G>A p.E881K (on ENST00000308370 / NM_001042544.1; = p.E844K on NM_003573.2) | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV52592057; called by muse, mutect2
- LYST | c.4040C>G p.S1347C | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.885); catalogued as rs767996620, COSV67715284; called by muse, mutect2, varscan2
- MAGEE2 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 50/50 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64898648; called by muse, mutect2, varscan2
- MAP2K4 | c.976C>G p.P326A | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62261317; called by muse, mutect2, varscan2
- MAP3K11 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 26/65 reads (40%) | catalogued as COSV100482263, COSV100482362; called by muse, varscan2
- MAP3K11 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.261); catalogued as rs866709252, COSV58418185; called by muse, varscan2
- MAP3K11 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753987214, COSV58422099; called by muse, mutect2, varscan2
- MBP | c.757G>A p.E253K (on ENST00000355994 / NM_001025101.2; = p.E135K on NM_002385.3) | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.873); catalogued as rs1334171636, COSV62828890; called by muse, mutect2, varscan2
- MCU | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV64065919; called by muse, mutect2, varscan2
- METTL3 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.137); catalogued as COSV52971625; called by muse, mutect2, varscan2
- MFSD4A | c.1065C>G p.F355L | Missense Mutation (SNP) | VAF 84/88 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65657177; called by muse, mutect2, varscan2
- MOCS3 | c.357G>A p.M119I | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV54868160; called by muse, mutect2, varscan2
- MPI | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV100086258, COSV60397772; called by muse, mutect2, varscan2
- MST1R | c.3944C>T p.S1315F | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV99618277; called by muse, mutect2
- MYLPF | c.234C>G p.I78M | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58444110; called by muse, mutect2, varscan2
- MYLPF | c.312C>A p.F104L | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV58444114; called by muse, mutect2, varscan2
- NARS1 | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV56878504; called by muse, mutect2, varscan2
- NARS1 | c.204G>C p.K68N | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.95); catalogued as rs757216420, COSV56878514; called by muse, mutect2, varscan2
- NAV3 | c.300C>G p.I100M | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57116564, COSV99887745; called by muse, mutect2, varscan2
- NDC80 | c.342G>C p.M114I | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV55250071; called by muse, mutect2, varscan2
- NDST1 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.836); catalogued as COSV55791384; called by muse, mutect2, varscan2
- NFIA | c.786G>C p.M262I | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.785); catalogued as COSV64545183; called by muse, mutect2, varscan2
- NOC3L | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV64930778; called by muse, mutect2, varscan2
- NPIPB15 | c.929C>G p.P310R | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV70438805; called by muse, mutect2
- NUFIP1 | c.705A>C p.E235D | Missense Mutation (SNP) | VAF 47/52 reads (90%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as COSV64792390; called by muse, mutect2, varscan2
- NUP155 | c.1766C>T p.P589L (on ENST00000231498 / NM_153485.3; = p.P530L on NM_004298.4) | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs375786815, COSV51535457; called by muse, mutect2, varscan2
- NUTM1 | c.2894C>T p.S965F | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV59219614; called by muse, mutect2, varscan2
- OR14C36 | c.218C>G p.S73C | Missense Mutation (SNP) | VAF 70/116 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV58602555, COSV58603090; called by muse, mutect2, varscan2
- OR1L4 | c.827C>A p.T276K | Missense Mutation (SNP) | VAF 38/43 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52341795; called by muse, varscan2
- OR52I2 | c.362C>G p.S121* | Nonsense Mutation (SNP) | VAF 4/68 reads (6%) | catalogued as COSV100442867; called by muse, mutect2
- OR56A1 | c.387C>G p.I129M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV57364092; called by muse, mutect2, varscan2
- PARK7 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.054); catalogued as rs1405805345, COSV58580886, COSV99071878; called by muse, mutect2, varscan2
- PCDH17 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 33/37 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1355877971, COSV64978106; called by muse, mutect2, varscan2
- PCDHB13 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.021); catalogued as COSV53396388, COSV53401731; called by muse, mutect2, varscan2
- PCDHB6 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as COSV50700934; called by muse, mutect2, varscan2
- PCDHB9 | c.730C>A p.Q244K | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); catalogued as rs1554282903; called by muse, mutect2, varscan2
- PCSK7 | c.2064G>C p.L688F | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as COSV54064405; called by muse, mutect2
- PDK2 | c.507C>G p.I169M | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.205); catalogued as rs1384238847, COSV99142933; called by muse, mutect2, varscan2
- PHF1 | c.1502C>T p.S501L | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs751052204, COSV53387231; called by muse, varscan2
- PIEZO2 | c.6451G>A p.E2151K | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as COSV53295303; called by muse, mutect2, varscan2
- PLK4 | c.2888C>G p.S963C | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as COSV54639769; called by muse, mutect2, varscan2
- POLA1 | c.2207C>G p.S736C | Missense Mutation (SNP) | VAF 38/38 reads (100%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.502); catalogued as COSV66891394; called by muse, mutect2, varscan2
- POLQ | c.5098G>C p.E1700Q | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.109); catalogued as COSV51763035; called by muse, mutect2, varscan2
- PPP2R5C | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV58277226; called by muse, mutect2, varscan2
- PRKDC | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1157805807, COSV58066214; called by muse, mutect2, varscan2
- PRSS3 | c.-125C>T | Splice Region (SNP) | VAF 23/46 reads (50%) | catalogued as rs190542730, COSV61557012; called by muse, varscan2
- PTK7 | c.2845C>G p.L949V | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV57852256; called by muse, mutect2, varscan2
- PXDN | c.3367G>A p.G1123R | Missense Mutation (SNP) | VAF 33/33 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1186843770, COSV53247671; called by muse, mutect2, varscan2
- RACK1 | c.749C>G p.A250G | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as COSV59320233, COSV59322785; called by muse, mutect2, varscan2
- RADIL | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.086); catalogued as rs1268125208, COSV68202527; called by muse, mutect2, varscan2
- RBM5 | c.1660C>T p.Q554* | Nonsense Mutation (SNP) | VAF 25/51 reads (49%) | catalogued as COSV100762219; called by muse, mutect2, varscan2
- RHOU | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.232); catalogued as COSV64209009, COSV64209258; called by muse, mutect2, varscan2
- RNF112 | c.40C>G p.R14G | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV71978987; called by muse, mutect2, varscan2
- RNF216 | c.211G>C p.E71Q (on ENST00000425013 / NM_207116.3; = p.E128Q on NM_207111.4) | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.544); catalogued as COSV66293022; called by muse, mutect2, varscan2
- RPL7L1 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV59035817; called by muse, mutect2, varscan2
- RPLP0 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.117); catalogued as COSV56115686; called by muse, mutect2, varscan2
- RSPH6A | c.769G>C p.D257H | Missense Mutation (SNP) | VAF 61/92 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55575325, COSV55576061; called by muse, mutect2, varscan2
- RTN4RL2 | c.389T>C p.L130P | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1283370194, COSV58653227; called by muse, mutect2, varscan2
- SCN3A | c.2662G>C p.V888L | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51826912, COSV99325683; called by muse, mutect2
- SEC16A | c.6185C>T p.S2062L | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs190567329, COSV51521209; called by muse, mutect2, varscan2
- SELE | c.1017C>G p.F339L | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60975236, COSV60978133; called by muse, mutect2, varscan2
- SFRP1 | c.894G>A p.M298I | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs757235545, COSV55177805; called by muse, mutect2, varscan2
- SFXN2 | c.889C>G p.L297V | Missense Mutation (SNP) | VAF 57/100 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV64013369; called by muse, mutect2, varscan2
- SIGLEC10 | c.1262G>C p.G421A | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV59487289; called by muse, mutect2, varscan2
- SLC17A2 | c.988G>A p.G330S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs369679171; called by muse, mutect2, varscan2
- SMG7 | c.3275C>G p.S1092C | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV61634739; called by muse, mutect2, varscan2
- SNRPA | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.597); catalogued as rs764836571, COSV99698813; called by muse, mutect2
- SNX2 | c.846G>C p.L282F | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.366); catalogued as COSV65349364; called by muse, mutect2, varscan2
- SOX5 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.031); catalogued as COSV58650899; called by muse, mutect2
- STAMBPL1 | c.26C>G p.S9C | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1364033664, COSV64226282; called by muse, mutect2, varscan2
- STAP2 | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1000539835, COSV74070973, COSV74071012; called by muse, mutect2, varscan2
- TAF3 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV60211469; called by muse, mutect2, varscan2
- TASOR2 | c.6529G>C p.V2177L | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1467722948, COSV60167466, COSV60169979; called by muse, mutect2, varscan2
- TBC1D4 | c.3190G>C p.D1064H | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66492788, COSV66493394; called by muse, mutect2, varscan2
- TENT4A | c.1991G>T p.R664I | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as COSV50103256; called by muse, mutect2, varscan2
- TIE1 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1303306163, COSV65251703; called by muse, mutect2
- TMOD1 | c.275G>C p.R92P | Missense Mutation (SNP) | VAF 27/29 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV52245442, COSV52253060; called by muse, mutect2, varscan2
- TNF | c.383C>G p.S128* | Nonsense Mutation (SNP) | VAF 45/95 reads (47%) | catalogued as COSV101403164; called by muse, mutect2, varscan2
- TRIM24 | c.2162G>A p.R721Q (on ENST00000343526 / NM_015905.3; = p.R687Q on NM_003852.4) | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as rs1256754225, COSV58979053; called by muse, mutect2, varscan2
- TTC3 | c.2777G>T p.G926V | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV61297137; called by muse, mutect2, varscan2
- TTC30B | c.1211G>C p.R404T | Missense Mutation (SNP) | VAF 167/190 reads (88%) | SIFT tolerated (0.27); PolyPhen benign (0.082); catalogued as rs756060494, COSV68809864; called by muse, mutect2, varscan2
- TTLL5 | c.3631C>G p.L1211V | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); catalogued as COSV54045603; called by muse, mutect2, varscan2
- USF3 | c.6370G>A p.D2124N | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57078065; called by muse, mutect2, varscan2
- USP15 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 106/245 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1181718349, COSV54800186; called by muse, mutect2, varscan2
- USP54 | c.2207C>T p.S736F | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.467); catalogued as COSV60448841; called by muse, mutect2, varscan2
- UTP25 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.111); catalogued as rs1368599854, COSV71966224; called by muse, mutect2, varscan2
- VLDLR | c.1233C>G p.I411M | Missense Mutation (SNP) | VAF 58/65 reads (89%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV66074805; called by muse, mutect2, varscan2
- WDR17 | c.3342T>G p.I1114M | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV54585684; called by muse, mutect2, varscan2
- WDR81 | c.3725C>G p.S1242C (on ENST00000409644 / NM_001163809.2; = p.S191C on NM_152348.4) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); catalogued as COSV58489186; called by muse, mutect2, varscan2
- WNT11 | c.97A>G p.T33A | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1169562111, COSV100490285; called by muse, mutect2, varscan2
- WNT9A | c.554G>A p.R185K | Missense Mutation (SNP) | VAF 93/101 reads (92%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55297701; called by muse, mutect2, varscan2
- ZBTB17 | c.2029C>T p.Q677* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as COSV100998991; called by muse, mutect2, varscan2
- ZBTB7B | c.1246G>C p.D416H (on ENST00000292176; = p.D450H on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV52691973, COSV52695202; called by muse, mutect2, varscan2
- ZEB1 | c.1567G>C p.E523Q | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.107); catalogued as COSV58056639; called by muse, mutect2, varscan2
- ZFYVE26 | c.7477G>C p.E2493Q | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV61334314; called by muse, mutect2, varscan2
- ZMYM6 | c.1898C>G p.S633* | Nonsense Mutation (SNP) | VAF 41/101 reads (41%) | catalogued as COSV100593095; called by muse, mutect2, varscan2
- ZNF106 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV55522632; called by muse, mutect2, varscan2
- ZNF211 | c.758G>A p.R253K (on ENST00000347302 / NM_198855.4; = p.R266K on NM_006385.5) | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1289164385, COSV53744184; called by muse, mutect2
- ZNF320 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.4); catalogued as rs1285033190, COSV67089140; called by muse, mutect2, varscan2
- ZNF483 | c.1994G>A p.C665Y | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58517438; called by muse, mutect2, varscan2
- ZNF609 | c.1903G>C p.E635Q | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as COSV58591180; called by muse, mutect2, varscan2
- ZNF770 | c.440C>A p.S147Y | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV62545244; called by muse, mutect2, varscan2
- BPTF | c.3686_3687del p.S1229* | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | called by pindel, varscan2
- FANCA | c.4291G>A p.E1431K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FAT1 | c.4280_4281dup p.T1428Sfs*20 | Frame Shift Ins (INS) | VAF 77/212 reads (36%) | called by mutect2, pindel, varscan2
- GAS2L2 | c.2512G>C p.E838Q | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACAN | c.6387G>C p.L2129= | Silent (SNP) | VAF 40/77 reads (52%) | catalogued as COSV61358543; called by muse, varscan2
- ADCY7 | c.2652C>T p.S884= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs143161770; called by muse, mutect2, varscan2
- ALKBH1 | c.70C>A p.R24= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as COSV53175099, COSV53175118; called by muse, mutect2, varscan2
- AMIGO1 | c.1161C>T p.V387= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV63990639; called by muse, mutect2, varscan2
- ATM | c.3501C>T p.I1167= | Silent (SNP) | VAF 59/107 reads (55%) | catalogued as rs1555091279, COSV53765718, COSV53779789; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP13A3 | c.2853C>T p.F951= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV55470206; called by muse, mutect2, varscan2
- CACNG3 | c.840C>G p.L280= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as COSV50086532; called by muse, mutect2, varscan2
- CARD10 | c.168C>A p.V56= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs762529561, COSV52660717; called by muse, mutect2, varscan2
- CLECL1 | c.189C>T p.F63= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV59932212; called by muse, mutect2, varscan2
- CLIP4 | c.297G>C p.V99= | Silent (SNP) | VAF 43/48 reads (90%) | catalogued as COSV60753378; called by muse, mutect2, varscan2
- DDX21 | c.435G>A p.E145= | Silent (SNP) | VAF 33/55 reads (60%) | catalogued as COSV62557071; called by muse, mutect2, varscan2
- DHX33 | c.1797G>C p.L599= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV56577990; called by muse, mutect2, varscan2
- ECI1 | c.225G>A p.L75= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as rs770144171, COSV57045373; called by muse, mutect2, varscan2
- F13A1 | c.102C>A p.G34= | Silent (SNP) | VAF 52/110 reads (47%) | catalogued as rs187027323, COSV53569182; called by muse, mutect2, varscan2
- FIBP | c.615C>T p.L205= | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as COSV57034435; called by muse, mutect2, varscan2
- GALR2 | c.798C>T p.L266= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV57165090; called by muse, mutect2, varscan2
- GLUD1 | c.1332G>A p.K444= | Silent (SNP) | VAF 36/222 reads (16%) | catalogued as COSV53281643; called by muse, mutect2, varscan2
- GSE1 | c.531C>T p.L177= | Silent (SNP) | VAF 32/54 reads (59%) | catalogued as COSV53676778; called by muse, mutect2, varscan2
- HPS4 | c.681G>A p.T227= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs751621468, COSV100404625, COSV61106257; called by muse, mutect2
- IFNL3 | c.33G>A p.L11= | Silent (SNP) | VAF 29/144 reads (20%) | catalogued as COSV69830260; called by muse, mutect2, varscan2
- IGHV3-11 | c.298C>T p.L100= | Silent (SNP) | VAF 80/310 reads (26%) | catalogued as rs548154544; called by muse, varscan2
- IGHV3-7 | c.298C>T p.L100= | Silent (SNP) | VAF 46/429 reads (11%) | catalogued as rs782389090; called by muse, mutect2
- IGSF11 | c.303C>A p.T101= (on ENST00000393775 / NM_001015887.3; = p.T100= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/65 reads (51%) | catalogued as COSV61170546; called by muse, mutect2, varscan2
- KCND3 | c.837C>T p.N279= | Silent (SNP) | VAF 42/89 reads (47%) | catalogued as rs761397595, COSV56191006; called by muse, mutect2, varscan2
- KMT2D | c.1035C>G p.L345= | Silent (SNP) | VAF 62/121 reads (51%) | catalogued as COSV56420481; called by muse, mutect2, varscan2
- LAMA5 | c.3432C>T p.P1144= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV99438963; called by muse, mutect2, varscan2
- MAGEB6 | c.985C>A p.R329= | Silent (SNP) | VAF 84/92 reads (91%) | catalogued as COSV66871893, COSV66872236; called by muse, mutect2, varscan2
- MAP2K3 | c.741C>G p.V247= (on ENST00000342679 / NM_145109.3; = p.V218= on NM_002756.4) | Silent (SNP) | VAF 37/136 reads (27%) | catalogued as rs1291901281, COSV100384605, COSV57578973; called by muse, mutect2, varscan2
- MPHOSPH8 | c.2157G>A p.L719= | Silent (SNP) | VAF 44/109 reads (40%) | catalogued as rs760624121, COSV64058091; called by muse, mutect2, varscan2
- MYO9A | c.228C>T p.L76= | Silent (SNP) | VAF 39/76 reads (51%) | catalogued as COSV100613572, COSV61859357; called by muse, mutect2, varscan2
- NEBL | c.1524C>T p.V508= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV65806357; called by muse, mutect2, varscan2
- NOMO1 | c.273G>A p.K91= | Silent (SNP) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- NUDT22 | c.717G>C p.L239= | Silent (SNP) | VAF 55/123 reads (45%) | catalogued as COSV54176110; called by muse, mutect2, varscan2
- OR4C15 | c.783C>T p.I261= (on ENST00000314644; = p.I207= on NM_001001920.2) | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as COSV58956221; called by muse, mutect2, varscan2
- OR51F2 | c.705G>A p.E235= | Silent (SNP) | VAF 32/34 reads (94%) | catalogued as COSV59065340, COSV59066280; called by muse, mutect2, varscan2
- PAPPA2 | c.4626C>G p.L1542= | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as COSV100867750, COSV62813842; called by muse, mutect2, varscan2
- PCDHA11 | c.2295G>A p.K765= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV56552359; called by muse, mutect2, varscan2
- PCDHB12 | c.1449C>T p.N483= | Silent (SNP) | VAF 74/169 reads (44%) | catalogued as COSV53401727; called by muse, mutect2, varscan2
- PHF1 | c.1443C>T p.F481= (on ENST00000374516 / NM_024165.3; = p.S446F on NM_002636.5) | Silent (SNP) | VAF 66/149 reads (44%) | catalogued as rs1156947507, COSV53387227; called by muse, varscan2
- PRKACA | c.699C>A p.A233= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV100431797, COSV58070574; called by muse, mutect2, varscan2
- RABL6 | c.1866G>A p.K622= | Silent (SNP) | VAF 13/14 reads (93%) | catalogued as COSV61041945; called by muse, mutect2, varscan2
- SELENOW | c.21C>G p.V7= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as rs1399197737, COSV101549470; called by muse, mutect2, varscan2
- SF3A1 | c.1983C>A p.V661= | Silent (SNP) | VAF 32/57 reads (56%) | catalogued as COSV53171623; called by muse, mutect2, varscan2
- SH3BP5 | c.594G>A p.E198= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as rs774017771, COSV53747004; called by muse, mutect2, varscan2
- SLC22A7 | c.441G>A p.A147= (on ENST00000372585 / NM_153320.2; = p.A145= on NM_006672.3) | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as rs750010211, COSV65356820; called by muse, mutect2, varscan2
- SLC35B2 | c.1110C>T p.I370= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV51492343; called by muse, mutect2, varscan2
- TBC1D9B | c.3642G>A p.V1214= (on ENST00000356834 / NM_198868.3; = p.V1197= on NM_015043.4) | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs377326329; called by muse, mutect2, varscan2
- TTC30B | c.12G>C p.L4= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV101282779; called by muse, mutect2, varscan2
- TTI2 | c.165C>A p.L55= | Silent (SNP) | VAF 38/94 reads (40%) | catalogued as COSV62453858; called by muse, mutect2
- UNC5A | c.678C>T p.I226= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs375167399; called by muse, mutect2, varscan2
- WNT10B | c.852C>T p.F284= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as COSV56406789; called by muse, mutect2, varscan2
- XPR1 | c.1590C>G p.L530= | Silent (SNP) | VAF 55/202 reads (27%) | catalogued as COSV62558561; called by muse, mutect2, varscan2
- ZBED9 | c.12C>G p.V4= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV71729819; called by muse, mutect2, varscan2
- ZSCAN22 | c.1437G>C p.L479= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as COSV61639719; called by muse, mutect2, varscan2
- PAX3 | c.586+427G>A | Intron (SNP) | VAF 124/129 reads (96%) | catalogued as rs747070982, COSV51345454; called by muse, varscan2
- PPP1R9A | c.2758-2022G>C | Intron (SNP) | VAF 21/56 reads (38%) | catalogued as COSV56889824, COSV56913870; called by muse, mutect2, varscan2
- PYGM | c.*2C>T | 3'UTR (SNP) | VAF 24/51 reads (47%) | catalogued as rs1052688003, COSV99376905; called by muse, mutect2, varscan2
- SLC22A20P | n.852G>C | RNA (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- STMP1 | chr7:135660123 del CAGTACTGCCAGCT | 5'Flank (DEL) | VAF 33/70 reads (47%) | called by mutect2, pindel, varscan2
